Surgical pathology report (de-identified scan), TCGA case TCGA-06-0686, project TCGA-GBM (Glioblastoma Multiforme), tissue source site Henry Ford Hospital, specimen TCGA-06-0686-01A (Primary Tumor).

[page 1 of 3]
Surgical Pathology Report

TCGA-06-0086

CLINICAL HISTORY

has mental status change and fatigue. On imaging there is a right temporal, lobulated, enhancing mass with central cystic component and extensive mass effect.

OPERATIVE DIAGNOSES
Not Given

Operation/Specimen: A: Brain, excision biopsy
B: Brain, right temporal tumor, excision biopsy

PATHOLOGICAL DIAGNOSIS:

A and B. Brain, right, excision: Glioblastoma. MIB-1 proliferation index: 65%.
See Comment.

COMMENT

The specimens are portions of cerebrum focally infiltrated and extensively effaced by an astrocytic neoplastic proliferation with nuclear anaplasia, prominent mitotic activity, exuberant microvascular cellular proliferation with vascular necrosis and thrombosis, and extensive tumor necrosis, i.e. a glioblastoma.

PROCEDURES/ADDENDA

MGMT Promoter Methylation

Date Ordered: Date Reported:

Interpretation

POSITIVE - Methylated MGMT promoter is detected.

Results-Comments

Testing was done on block

TEST DESCRIPTION: Bisulfite treatment of DNA followed by PCR amplification of both methylated and unmethylated MGMT promoter sequences, with products detected by gel electrophoresis.

[page 2 of 3]
[REDACTED]

FDA COMMENT: The above data are not to be construed as the results from a stand-alone diagnostic test. This test was developed and its performance characteristics determined by the [REDACTED] laboratory as required by CLIA ' [REDACTED] regulations. It has not been cleared or approved for specific uses by the U.S. Food and Drug Administration (FDA). The FDA has determined that such clearance or approval is not necessary. These results are provided for informational purposes only, and should be interpreted only in the context of established procedures and/or diagnostic criteria.

[REDACTED]

INTRA-OPERATIVE CONSULTATION

A. Brain, excision biopsy, touch prep and smears: High histological grade glioma (C/W glioblastoma). [REDACTED] Frozen section performed at [REDACTED] Hospital and results reported to the Physician of Record. [REDACTED]

[REDACTED]

GROSS DESCRIPTION

A.
Received fresh, large portion of thick, diffluent, tannish-brown material, 3 x 3 x 0.8 cm. In total, A1 and A2.

B.
SPECIMEN: Right temporal tumor.
FIXATIVE: None.
GENERAL: Received is a 1.5 x 0.7 x 0.5 cm. aggregate of irregular, tan-gray to white focally hemorrhagic soft tissue fragments.
SECTIONS: B1 entirely submitted.

[REDACTED]

MICROSCOPIC DESCRIPTION

IMMUNOHISTOCHEMISTRY: The GFAP demonstrates gliofibrillogenesis by the neoplastic cells. About 2% of the tumor cells express the p53 protein. With the MIB-1 there is a proliferation index of about 65% throughout the tumor.

ICD-9(s):
239.6 239.6

[REDACTED]

Histo Data

Part A: Brain, excision biopsy

Taken:	Received:	Block	Ordered	Comment
Stain/cnt				
mGFAP-DA x 1		1		
H/E x 1		1		
MGMT x 1		1		
MIB1-DA x 1		1		
P53DO7 x 1		1		

[page 3 of 3]
[REDACTED]

TPS H/E x 1	1
H/E x 1	2
H/E x 1	3

Part B: Brain, right temporal tumor, excision biopsy

Taken: [REDACTED]	Received: [REDACTED]		
Stain/cnt	Block	Ordered	Comment
H/E x 1	1	[REDACTED]	

*** End of Report ***

[REDACTED]

Source: NCI Genomic Data Commons file 3ca4f725-2292-45aa-951e-2a9af2550615 (TCGA-06-0686.4D50D9DB-EECF-4444-B6B7-DA1C90BE713D.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).